Somatic mutation profile of cancer-model specimen HCM-CSHL-0089-C25-85A (3D Organoid; aliquot HCM-CSHL-0089-C25-85A-01D-A77E-36), derived from the primary tumor of HCMI case HCM-CSHL-0089-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 62.5 years (22,825 days).
Specimen HCM-CSHL-0089-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfcd3480-a7fa-472c-b43f-807efbb54add.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0089-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0089-C25-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7b37498-9aa2-4298-9d58-51492fd34d28

The open-access MAF lists 86 somatic variants for this specimen: 60 protein-altering or splice-affecting, 17 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 17, Intron 6, Frame Shift Del 6, Frame Shift Ins 6, 5'Flank 1, RNA 1, 5'UTR 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 464/464 reads (100%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 214/238 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TG | c.7007G>A p.R2336Q | Missense Mutation (SNP) | VAF 218/866 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912650, CM063181, COSV55069861; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 361/362 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 344/544 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs763733632; called by muse, mutect2, varscan2
- ADAMTS4 | c.2119G>T p.A707S | Missense Mutation (SNP) | VAF 86/130 reads (66%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV63491126; called by muse, mutect2
- ARID3A | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 126/263 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs781106095, COSV55046653; called by muse, mutect2, varscan2
- ARMC6 | c.1499C>T p.A500V (on ENST00000392336; = p.A475V on NM_033415.4) | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.552); catalogued as rs1029406116; called by muse, mutect2, varscan2
- CDK5R2 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV56936808; called by muse, mutect2, varscan2
- COL6A6 | c.2708G>A p.R903Q | Missense Mutation (SNP) | VAF 83/146 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1313232339, COSV62024644; called by muse, mutect2, varscan2
- CYP4F11 | c.572T>A p.M191K | Missense Mutation (SNP) | VAF 108/221 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1461992996; called by muse, mutect2, varscan2
- DLGAP2 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 180/306 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as rs1309261843; called by muse, mutect2, varscan2
- DUOX1 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 33/351 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144848407; called by muse, mutect2
- EIF2AK1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1384063838, COSV52240872; called by muse, mutect2, varscan2
- FAM216B | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.943); catalogued as COSV58270150; called by muse, mutect2, varscan2
- FAM71A | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 49/246 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202026670, COSV99674804; called by muse, mutect2, varscan2
- FAT3 | c.8698G>A p.E2900K | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV53173634; called by muse, mutect2
- JAK3 | c.2519G>A p.R840H | Missense Mutation (SNP) | VAF 220/428 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as rs140837014; called by muse, varscan2
- KMT2D | c.13895del p.P4632Hfs*8 | Frame Shift Del (DEL) | VAF 153/233 reads (66%) | catalogued as CD114933; called by mutect2, pindel, varscan2
- MYOZ3 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 171/291 reads (59%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as rs766224195, COSV51739562; called by muse, mutect2, varscan2
- NAV2 | c.2803C>G p.R935G (on ENST00000396087 / NM_001244963.2; = p.R912G on NM_145117.5) | Missense Mutation (SNP) | VAF 42/476 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100584519; called by muse, mutect2
- NGFR | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 73/329 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1331306094; called by muse, mutect2, varscan2
- OGDHL | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 84/169 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs767864251, COSV65100729; called by muse, mutect2, varscan2
- OR13G1 | c.543G>T p.L181F | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV62943607; called by muse, mutect2, varscan2
- PSMA1 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.242); catalogued as rs770318291; called by muse, mutect2, varscan2
- PTPRD | c.5188C>T p.R1730W | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775122610, COSV61982613; called by muse, mutect2, varscan2
- RUNX1T1 | c.1219G>A p.G407S (on ENST00000265814 / NM_001198628.1; = p.G380S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 224/663 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs202121288; called by muse, mutect2, varscan2
- SIDT2 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs777557219; called by muse, varscan2
- SMAD4 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 96/96 reads (100%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs1064796102, COSV61685043, COSV61685722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SULT4A1 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 319/510 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV50782227; called by muse, mutect2, varscan2
- THBS2 | c.1922C>T p.T641M | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as rs1451706316, COSV64679569; called by muse, mutect2, varscan2
- TUBB8B | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as rs1438106680; called by muse, mutect2
- UNC5B | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 120/291 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs1157473537, COSV58975273, COSV58975519; called by muse, mutect2, varscan2
- VAV1 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 75/198 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as rs774426463; called by muse, mutect2, varscan2
- ZDBF2 | c.563C>A p.A188D | Missense Mutation (SNP) | VAF 114/170 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV65622248; called by muse, mutect2, varscan2
- ZNF569 | c.389dup p.S132Ffs*7 | Frame Shift Ins (INS) | VAF 36/84 reads (43%) | catalogued as rs752923644; called by mutect2, pindel, varscan2
- ACSL5 | c.1871A>G p.Q624R (on ENST00000354273; = p.Q680R on NM_016234.3) | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACVR2A | c.1309_1310del p.K437Efs*19 | Frame Shift Del (DEL) | VAF 65/156 reads (42%) | called by mutect2, pindel, varscan2
- ARMCX3 | c.654dup p.S219Ifs*17 | Frame Shift Ins (INS) | VAF 22/22 reads (100%) | called by mutect2, varscan2
- CIC | c.3727_3728insT p.A1243Vfs*12 | Frame Shift Ins (INS) | VAF 84/236 reads (36%) | called by mutect2, pindel, varscan2
- CLNK | c.533dup p.E179* | Frame Shift Ins (INS) | VAF 69/177 reads (39%) | called by mutect2, pindel, varscan2
- CNBD1 | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- EPM2AIP1 | c.1055T>G p.F352C | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FANCG | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 143/398 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FBXO33 | c.1131_1139delinsG p.F377Lfs*3 | Frame Shift Del (DEL) | VAF 65/310 reads (21%) | called by pindel, varscan2*
- GNAT3 | c.107T>A p.L36Q | Missense Mutation (SNP) | VAF 84/196 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- H4C5 | c.112_123del p.L38_R41del | In Frame Del (DEL) | VAF 28/268 reads (10%) | called by mutect2, pindel
- HAVCR1 | c.476C>A p.T159K | Missense Mutation (SNP) | VAF 292/480 reads (61%) | SIFT tolerated (0.36); PolyPhen benign (0.063); called by mutect2, varscan2
- HOMER2 | c.442_445dup p.D149Gfs*3 (on ENST00000304231 / NM_199330.3; = p.D138Gfs*3 on NM_004839.4) | Frame Shift Ins (INS) | VAF 92/264 reads (35%) | called by mutect2, varscan2
- ITGB6 | c.2029_2039del p.E677Yfs*8 | Frame Shift Del (DEL) | VAF 17/164 reads (10%) | called by mutect2, pindel
- KLK6 | c.361C>A p.L121I | Missense Mutation (SNP) | VAF 169/312 reads (54%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEXMIF | c.3808T>A p.S1270T | Missense Mutation (SNP) | VAF 178/178 reads (100%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCBP3 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- PNLIP | c.752dup p.M251Ifs*5 | Frame Shift Ins (INS) | VAF 16/134 reads (12%) | called by mutect2, pindel, varscan2
- PPP1R15B | c.566G>A p.S189N | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PRPF40A | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 330/537 reads (61%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- PXMP2 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 38/566 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2
- SLC41A3 | c.302del p.D101Afs*3 | Frame Shift Del (DEL) | VAF 32/70 reads (46%) | called by mutect2, pindel, varscan2
- TMEM94 | c.2605del p.M869Wfs*39 | Frame Shift Del (DEL) | VAF 95/185 reads (51%) | called by mutect2, pindel, varscan2
- ZNF396 | c.338A>C p.Q113P | Missense Mutation (SNP) | VAF 139/243 reads (57%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- CHD6 | c.6708C>T p.S2236= | Silent (SNP) | VAF 256/520 reads (49%) | catalogued as rs951814095; called by muse, mutect2, varscan2
- ELFN2 | c.57C>T p.A19= | Silent (SNP) | VAF 207/321 reads (64%) | catalogued as rs756407312; called by muse, mutect2, varscan2
- HUNK | c.570G>A p.E190= | Silent (SNP) | VAF 41/78 reads (53%) | catalogued as COSV54227106; called by muse, mutect2, varscan2
- ITGBL1 | c.771G>T p.P257= | Silent (SNP) | VAF 44/136 reads (32%) | called by muse, mutect2, varscan2
- KBTBD11 | c.1179C>T p.S393= | Silent (SNP) | VAF 112/502 reads (22%) | catalogued as rs781084410, COSV100207492; called by muse, mutect2, varscan2
- MATN4 | c.207C>T p.N69= | Silent (SNP) | VAF 123/285 reads (43%) | catalogued as COSV59212971; called by muse, mutect2, varscan2
- MUC4 | c.14625C>T p.N4875= (on ENST00000463781 / NM_018406.7; = p.N639= on NM_004532.6) | Silent (SNP) | VAF 90/191 reads (47%) | catalogued as rs1297779381; called by muse, mutect2, varscan2
- NAT1 | c.279T>G p.V93= | Silent (SNP) | VAF 134/224 reads (60%) | called by muse, mutect2, varscan2
- OR10A4 | c.315C>T p.F105= | Silent (SNP) | VAF 14/346 reads (4%) | called by muse, mutect2
- OR2T12 | c.516C>T p.I172= | Silent (SNP) | VAF 125/521 reads (24%) | catalogued as rs1186607809, COSV58777432, COSV58778756; called by muse, mutect2, varscan2
- OR2T6 | c.138C>T p.I46= | Silent (SNP) | VAF 31/59 reads (53%) | called by muse, mutect2, varscan2
- PEG3 | c.2247G>A p.A749= | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as rs770435859, COSV55636264; called by muse, mutect2, varscan2
- PNCK | c.120C>T p.L40= (on ENST00000340888 / NM_001366975.1; = p.L123= on NM_001039582.3) | Silent (SNP) | VAF 10/245 reads (4%) | catalogued as rs1345807750, COSV61744665; called by muse, mutect2
- PPP2R1A | c.1182G>T p.V394= | Silent (SNP) | VAF 114/205 reads (56%) | called by muse, mutect2, varscan2
- SKOR1 | c.876C>T p.G292= | Silent (SNP) | VAF 121/187 reads (65%) | catalogued as rs746508508; called by muse, mutect2, varscan2
- USP35 | c.2116A>C p.R706= | Silent (SNP) | VAF 23/145 reads (16%) | called by muse, mutect2, varscan2
- ZBTB20 | c.420C>T p.I140= (on ENST00000474710 / NM_001164342.2; = p.I67= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 181/365 reads (50%) | catalogued as COSV61847669; called by muse, mutect2, varscan2
- ARHGEF19 | c.1138-94C>G | Intron (SNP) | VAF 29/60 reads (48%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130916414 G>A | 5'Flank (SNP) | VAF 54/174 reads (31%) | called by muse, mutect2, varscan2
- DENND2B | c.2283-29C>T | Intron (SNP) | VAF 30/708 reads (4%) | called by muse, mutect2
- KCNU1 | c.2010-17035G>A | Intron (SNP) | VAF 79/230 reads (34%) | catalogued as rs769673898; called by muse, mutect2, varscan2
- LINC01551 | n.1255-5467G>C | Intron (SNP) | VAF 9/56 reads (16%) | catalogued as rs1420278730; called by muse, mutect2, varscan2
- MYLK | c.3652+49C>T | Intron (SNP) | VAF 96/194 reads (49%) | called by muse, mutect2, varscan2
- PDCD6 | c.-48G>A | 5'UTR (SNP) | VAF 131/653 reads (20%) | catalogued as rs752212065; called by muse, mutect2, varscan2
- TPI1 | c.227-459T>A | Intron (SNP) | VAF 22/244 reads (9%) | called by muse, mutect2
- TUBB7P | n.37G>A | RNA (SNP) | VAF 32/111 reads (29%) | catalogued as rs782640561; called by muse, varscan2
